Somatic mutation profile of tumor specimen TCGA-66-2787-01A (aliquot TCGA-66-2787-01A-01D-0983-08) from TCGA case TCGA-66-2787, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 57.8 years (21,124 days).
Specimen TCGA-66-2787-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc9f4ebe-21b7-4155-9eff-f683d1382257.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2787-11A (Solid Tissue Normal), aliquot TCGA-66-2787-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3844d98-3294-4d98-bc13-398711442a40

The open-access MAF lists 497 somatic variants for this specimen: 396 protein-altering or splice-affecting, 81 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 332, Silent 81, Nonsense Mutation 30, Frame Shift Del 13, Intron 10, Splice Site 8, Splice Region 6, RNA 5, Frame Shift Ins 3, In Frame Del 2, 3'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.150G>C p.Q50H | Missense Mutation (SNP) | VAF 48/106 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58692109, COSV58697920, COSV58703332; called by muse, mutect2, varscan2
- NFE2L2 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553487942, COSV67960075, COSV67960449, COSV67960680; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.1963G>T p.G655* | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as COSV58052869; called by muse, mutect2, varscan2
- ABCG8 | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as rs750352877, BM1497300, COSV55394538; called by muse, mutect2
- ACAN | c.4360G>A p.G1454R | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1209165088, COSV61363684; called by muse, varscan2
- ACHE | c.926C>G p.A309G | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV53819130; called by muse, mutect2, varscan2
- ACOX1 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV53131375; called by muse, mutect2, varscan2
- ADAMTS9 | c.2834G>T p.S945I | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55784721; called by muse, mutect2, varscan2
- ADGRB3 | c.1424G>T p.W475L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.926); catalogued as COSV101002090; called by muse, mutect2, varscan2
- ADGRL1 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV61565410, COSV61566057; called by muse, mutect2, varscan2
- ADGRV1 | c.7169G>C p.S2390T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV67989144; called by muse, varscan2
- AFDN | c.4650C>G p.S1550R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as COSV60048471; called by muse, mutect2, varscan2
- ALG13 | c.3397G>T p.V1133L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV52641332; called by muse, mutect2, varscan2
- ALX1 | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as rs1565939216, COSV57493041; called by muse, mutect2, varscan2
- AMBN | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.251); catalogued as rs141521373; called by muse, mutect2, varscan2
- ANKFN1 | c.1059A>T p.K353N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV59451985; called by muse, mutect2, varscan2
- ANKRD26 | c.4333G>T p.E1445* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | catalogued as COSV65776509; called by muse, mutect2, varscan2
- ANKRD30A | c.3527C>G p.T1176R (on ENST00000611781; = p.T1120R on NM_052997.2) | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV64614237; called by muse, mutect2, varscan2
- ANKS6 | c.2290A>T p.S764C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV62050929; called by muse, mutect2, varscan2
- APOC3 | c.278C>A p.P93Q | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV52636033; called by muse, mutect2, varscan2
- ARHGEF10 | c.1878C>A p.N626K (on ENST00000398564; = p.N601K on NM_014629.4) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100036099, COSV50658063; called by muse, mutect2, varscan2
- ARHGEF11 | c.1516G>T p.D506Y | Missense Mutation (SNP) | VAF 70/120 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63813977; called by muse, varscan2
- ASTN2 | c.395C>A p.A132E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.141); catalogued as rs893223522, COSV57792628; called by muse, mutect2, varscan2
- ATG2B | c.4175G>T p.G1392V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55891193; called by muse, mutect2, varscan2
- ATP1A3 | c.1062G>T p.M354I (on ENST00000545399 / NM_001256214.2; = p.M341I on NM_152296.5) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57488974; called by muse, mutect2, varscan2
- ATP5F1A | c.1556A>T p.H519L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.14); catalogued as COSV56360891; called by mutect2, varscan2
- AXDND1 | c.2388G>C p.K796N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV62644672; called by muse, mutect2, varscan2
- BCAM | c.976G>T p.G326* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV54303256; called by muse, mutect2, varscan2
- BEND3 | c.1184A>T p.Q395L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.452); catalogued as COSV64681506; called by muse, mutect2, varscan2
- BIVM | c.1500T>A p.D500E | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV57280758; called by muse, mutect2, varscan2
- BIVM | c.1501G>T p.G501W | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV57280776; called by muse, mutect2, varscan2
- BPTF | c.8311C>A p.L2771M | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV58840633; called by muse, mutect2, varscan2
- BRCA2 | c.2979G>C p.W993C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as CM119541, COSV66456866; called by muse, mutect2, varscan2
- BRINP2 | c.1190G>A p.C397Y | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV64178505; called by muse, mutect2, varscan2
- BTBD17 | c.1348C>A p.R450S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64730209; called by muse, mutect2, varscan2
- BTNL8 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.188); catalogued as COSV51459724; called by muse, mutect2, varscan2
- C10orf71 | c.51C>G p.S17R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60509671; called by muse, mutect2, varscan2
- C2orf16 | c.529A>C p.K177Q | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); catalogued as COSV68646453; called by muse, mutect2, varscan2
- C8orf34 | c.1406G>T p.G469V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.561); catalogued as COSV57406392; called by muse, mutect2
- CAD | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs765440558, COSV53028749; called by mutect2, varscan2
- CAND1 | c.2866G>C p.G956R | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73389682; called by muse, mutect2, varscan2
- CAVIN1 | c.350T>A p.V117D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63812245; called by muse, mutect2, varscan2
- CCDC148 | c.1535C>A p.T512K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99321735; called by muse, mutect2, varscan2
- CCDC92 | c.481C>A p.Q161K | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99436003; called by mutect2, varscan2
- CCKBR | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV58102877; called by muse, mutect2, varscan2
- CCN4 | c.833A>T p.Q278L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV51533376; called by muse, mutect2, varscan2
- CCR1 | c.818G>T p.C273F | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1559520122, COSV56122527; called by muse, mutect2, varscan2
- CCT8L2 | c.175T>C p.F59L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769688664, COSV63462999; called by mutect2, varscan2
- CD200R1L | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV101236668; called by mutect2, varscan2
- CD96 | c.1513G>T p.V505F (on ENST00000283285 / NM_198196.3; = p.V489F on NM_005816.5) | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs372441714, COSV51918649; called by muse, mutect2, varscan2
- CDC20 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as rs761745431, COSV60522415; called by muse, mutect2, varscan2
- CDH9 | c.2344G>T p.G782W | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50338162, COSV99163020; called by muse, mutect2, varscan2
- CDK14 | c.465G>A p.K155= (on ENST00000380050 / NM_001287135.2; = p.K137= on NM_012395.3) | Splice Region (SNP) | VAF 15/37 reads (41%) | catalogued as COSV56041542; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2741G>T p.G914V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV100575810; called by muse, mutect2, varscan2
- CEP128 | c.3009G>T p.R1003S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs370431744, COSV55381990; called by mutect2, varscan2
- CFAP44 | c.610G>T p.G204W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55613152; called by muse, mutect2, varscan2
- CFAP69 | c.101C>A p.T34K | Missense Mutation (SNP) | VAF 67/143 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.144); catalogued as rs777707428, COSV60186719; called by muse, mutect2, varscan2
- CFAP91 | c.1819C>G p.R607G | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56339324, COSV56342248; called by muse, mutect2, varscan2
- CHD1 | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52342071; called by muse, mutect2, varscan2
- CHD6 | c.3887G>A p.R1296K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.023); catalogued as COSV58559100; called by muse, mutect2, varscan2
- CHD7 | c.1962G>T p.K654N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV71112422; called by muse, mutect2, varscan2
- CHP2 | c.540C>G p.S180= | Splice Region (SNP) | VAF 57/187 reads (30%) | catalogued as COSV55650285, COSV55650742, COSV55650987; called by muse, mutect2, varscan2
- CHST9 | c.936A>T p.K312N | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52441665; called by muse, mutect2, varscan2
- CLIP4 | c.1969G>A p.E657K | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV60750236; called by muse, varscan2
- CLRN1 | c.171T>A p.F57L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58995156; called by muse, mutect2, varscan2
- CLVS2 | c.677T>G p.I226R | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51565217; called by muse, mutect2, varscan2
- CNR1 | c.1011G>T p.M337I | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV62988142, COSV62988733; called by muse, mutect2, varscan2
- CNTN1 | c.478C>A p.P160T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761808311, COSV61641841; called by mutect2, varscan2
- CNTN6 | c.2772G>T p.E924D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.825); catalogued as COSV63160587, COSV63178210; called by muse, mutect2, varscan2
- COL11A1 | c.4447G>T p.G1483* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as COSV62188452; called by muse, mutect2, varscan2
- COL1A2 | c.3715G>T p.E1239* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV51960900; called by muse, mutect2, varscan2
- COL6A1 | c.2251G>T p.V751L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100720532; called by mutect2, varscan2
- COLQ | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM080164, COSV67525225; called by muse, mutect2, varscan2
- CPEB1 | c.1450C>A p.Q484K (on ENST00000617958; = p.Q419K on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV55619954; called by muse, mutect2, varscan2
- CRISP1 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59994113, COSV59994245; called by muse, mutect2
- CRTC3 | c.578-2A>G p.X193_splice | Splice Site (SNP) | VAF 21/57 reads (37%) | catalogued as COSV51598090; called by muse, mutect2, varscan2
- CRYBB2 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68005568; called by muse, mutect2, varscan2
- CSF1 | c.980G>T p.R327M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.87); catalogued as COSV60034150; called by muse, mutect2, varscan2
- CSGALNACT1 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.687); catalogued as COSV100175814; called by mutect2, varscan2
- CSMD1 | c.10565G>A p.G3522D (on ENST00000520002; = p.G3521D on NM_033225.6) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153998, COSV59344303; called by muse, mutect2, varscan2
- CSMD3 | c.4142G>T p.C1381F (on ENST00000297405 / NM_001363185.1; = p.C1277F on NM_052900.3) | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476246136, COSV52229828, COSV52330487; called by muse, mutect2, varscan2
- CSMD3 | c.2309C>G p.S770C (on ENST00000297405 / NM_001363185.1; = p.S666C on NM_052900.3) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV52229847, COSV52268030; called by muse, mutect2, varscan2
- CTNNA2 | c.466G>T p.V156L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as rs575691331, COSV63581258; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1311A>T p.L437F | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV54745445; called by muse, mutect2, varscan2
- CWH43 | c.2003A>C p.K668T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV56940575; called by muse, mutect2, varscan2
- CYBB | c.1149T>G p.P383= | Splice Region (SNP) | VAF 14/27 reads (52%) | catalogued as COSV66085784; called by muse, mutect2, varscan2
- CYP19A1 | c.1377C>A p.H459Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV53060471; called by muse, mutect2, varscan2
- CYP4X1 | c.862G>T p.D288Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64151169; called by muse, mutect2, varscan2
- DCLK2 | c.1337G>T p.R446L | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs772172177, COSV56204210, COSV56206882; called by muse, mutect2, varscan2
- DCTN1 | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62620879; called by muse, mutect2, varscan2
- DDX4 | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as COSV61755820; called by muse, mutect2, varscan2
- DEFB112 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.628); catalogued as COSV59182783; called by muse, mutect2, varscan2
- DIRAS1 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104405249, COSV60216105; called by muse, varscan2
- DNAH11 | c.7550C>A p.T2517K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60964877; called by muse, mutect2, varscan2
- DNAH2 | c.1666C>G p.R556G | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as COSV50016384; called by muse, mutect2, varscan2
- DNAH5 | c.11664C>A p.Y3888* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV54229389, COSV54236409; called by muse, mutect2, varscan2
- DNAH5 | c.4391A>T p.Q1464L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as COSV54236417; called by mutect2, varscan2
- DNAH8 | c.3663G>T p.M1221I | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV59460276, COSV59486547; called by muse, mutect2, varscan2
- DNAH9 | c.2818G>A p.G940R | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV52358676; called by muse, mutect2
- DNMT3B | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs138596278; ClinVar: uncertain significance; called by mutect2, varscan2
- DOCK2 | c.3485C>A p.A1162E | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV56955470, COSV56969095; called by muse, mutect2, varscan2
- DOCK5 | c.4859A>T p.E1620V | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV52405489; called by muse, mutect2, varscan2
- DPP8 | c.1393G>A p.E465K (on ENST00000341861 / NM_001320875.2; = p.E449K on NM_017743.6) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0.038); catalogued as COSV55680405; called by muse, mutect2, varscan2
- DPPA2 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs909241283, COSV72118167; called by muse, mutect2, varscan2
- DTNA | c.736T>A p.C246S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52011598; called by muse, mutect2, varscan2
- DYNC2H1 | c.12532A>T p.T4178S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV62098636; called by muse, mutect2, varscan2
- EAF2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/78 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV56544964; called by muse, varscan2
- EDN3 | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV61108733; called by muse, mutect2, varscan2
- EFCAB6 | c.1492G>A p.V498I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV53066513; called by muse, mutect2, varscan2
- EIF4B | c.110C>A p.P37Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV50404570; called by muse, mutect2, varscan2
- EIF4E3 | c.574G>C p.E192Q (on ENST00000425534 / NM_001134651.2; = p.E86Q on NM_173359.5) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.076); catalogued as COSV55205520; called by muse, mutect2, varscan2
- ENOX2 | c.1775G>T p.G592V (on ENST00000338144 / NM_001382520.1; = p.G563V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57654094, COSV57657069; called by muse, mutect2, varscan2
- EPB41L3 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100550626; called by mutect2, varscan2
- EPHA5 | c.3040G>A p.G1014S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.588); catalogued as rs149835568; called by muse, mutect2, varscan2
- EPHA6 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101061406, COSV67579604; called by muse, mutect2, varscan2
- EPHB1 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs754797097, COSV67664762; called by muse, mutect2, varscan2
- EPHB2 | c.2905A>T p.N969Y (on ENST00000400191 / NM_001309193.2; = p.N970Y on NM_004442.7) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); catalogued as COSV65863708; called by muse, mutect2, varscan2
- ERBIN | c.1605C>A p.T535= | Splice Region (SNP) | VAF 32/92 reads (35%) | catalogued as COSV52320654; called by muse, varscan2
- EVC2 | c.283+2T>C p.X95_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | catalogued as COSV60396760; called by muse, mutect2, varscan2
- EXOC1 | c.2434G>T p.V812F | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100638058, COSV62120957; called by muse, mutect2
- F13A1 | c.481T>A p.Y161N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV53561670; called by muse, mutect2, varscan2
- FABP7 | c.241T>C p.C81R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV62956756; called by muse, mutect2, varscan2
- FAH | c.1231A>T p.K411* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as COSV55722290; called by muse, mutect2, varscan2
- FAM135B | c.369-2A>T p.X123_splice | Splice Site (SNP) | VAF 9/58 reads (16%) | catalogued as COSV50529928; called by muse, mutect2, varscan2
- FAM160A2 | c.1042A>T p.I348F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV56411780; called by muse, mutect2
- FANK1 | c.474G>A p.R158= | Splice Region (SNP) | VAF 15/43 reads (35%) | catalogued as rs766493086, COSV64156778; called by muse, mutect2, varscan2
- FASTKD3 | c.314G>T p.R105I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as COSV52945024; called by muse, mutect2, varscan2
- FAT4 | c.2303G>A p.G768D | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV67881619, COSV67891503; called by muse, mutect2, varscan2
- FAXDC2 | c.857G>T p.C286F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV58172990; called by muse, mutect2, varscan2
- FBN2 | c.2261G>T p.G754V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.705); catalogued as COSV52525227; called by muse, mutect2, varscan2
- FBXO7 | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.794); catalogued as COSV56679611; called by muse, mutect2, varscan2
- FER | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV55296060; called by muse, mutect2, varscan2
- FOLH1 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV57051748; called by muse, mutect2, varscan2
- FRZB | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV54554832; called by muse, mutect2, varscan2
- FSCB | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs867061377, COSV61218695; called by muse, mutect2, varscan2
- FTHL17 | c.183C>A p.D61E | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.174); catalogued as COSV63266432, COSV63267272; called by muse, mutect2, varscan2
- GABRA2 | c.178G>T p.G60* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV62916468; called by muse, mutect2, varscan2
- GAS7 | c.187C>A p.P63T (on ENST00000432992 / NM_201433.2; = p.P3T on NM_201432.2) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.63); PolyPhen probably damaging (0.981); catalogued as COSV60439162; called by muse, mutect2, varscan2
- GBX1 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV52548039; called by muse, mutect2, varscan2
- GCK | c.547G>T p.G183W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100357377; called by muse, mutect2, varscan2
- GJA1 | c.893G>C p.C298S | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV56998584; called by muse, mutect2, varscan2
- GK | c.830A>G p.Q277R (on ENST00000427190 / NM_001205019.2; = p.Q271R on NM_000167.6) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV66737643; called by muse, mutect2, varscan2
- GLB1L2 | c.87-1G>T p.X29_splice | Splice Site (SNP) | VAF 13/25 reads (52%) | catalogued as COSV60279370; called by muse, mutect2, varscan2
- GLIS3 | c.1556C>A p.T519K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV60931793; called by mutect2, varscan2
- GPAM | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as rs754776897, COSV62081126; called by muse, mutect2, varscan2
- GPR139 | c.545T>C p.V182A | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV58503632; called by muse, mutect2, varscan2
- GPR156 | c.1273C>G p.P425A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV59940956; called by muse, mutect2, varscan2
- GPRIN3 | c.1360A>G p.K454E | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60885438; called by muse, mutect2, varscan2
- GRM5 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV59613297; called by muse, mutect2, varscan2
- H4C3 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV58090865; called by muse, mutect2, varscan2
- HEPH | c.2657T>G p.V886G (on ENST00000343002; = p.V619G on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57966779; called by muse, mutect2, varscan2
- HEPHL1 | c.674A>G p.E225G | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV59893609; called by muse, mutect2, varscan2
- HGF | c.2171A>T p.K724M | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as rs1299244618, COSV55952234; called by muse, mutect2, varscan2
- HGS | c.1942C>T p.P648S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1462055595, COSV61268711; called by muse, mutect2, varscan2
- HOMEZ | c.1370C>G p.P457R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.092); catalogued as COSV62537419; called by muse, varscan2
- HRC | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as COSV53257327, COSV99418549; called by muse, mutect2, varscan2
- HTR2A | c.648G>T p.Q216H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV66327695; called by muse, mutect2, varscan2
- IFT80 | c.1807G>C p.D603H | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV58449352; called by muse, mutect2, varscan2
- IGF2BP1 | c.1166G>T p.S389I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV51733131; called by muse, mutect2, varscan2
- IGHV2-5 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs782068483; called by muse, mutect2, varscan2
- IGSF10 | c.4117G>T p.A1373S | Missense Mutation (SNP) | VAF 37/205 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.039); catalogued as COSV56787760; called by muse, mutect2, varscan2
- IL4 | c.302A>G p.K101R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1415459279, COSV51503314; called by muse, mutect2
- INSR | c.2078A>G p.D693G | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57166030; called by muse, mutect2, varscan2
- INTS10 | c.1674G>T p.K558N | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.286); catalogued as COSV67604535; called by muse, mutect2, varscan2
- ITPRID2 | c.3614C>T p.P1205L | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV57473470; called by muse, mutect2, varscan2
- KCNA4 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV60253776; called by muse, mutect2, varscan2
- KCNN2 | c.1295T>A p.L432Q (on ENST00000264773; = p.L644Q on NM_021614.4) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53292858; called by muse, mutect2, varscan2
- KDM5B | c.2548T>C p.Y850H | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV52509698; called by muse, mutect2, varscan2
- KIAA1549 | c.3415G>T p.E1139* | Nonsense Mutation (SNP) | VAF 52/115 reads (45%) | catalogued as COSV54318938; called by muse, mutect2, varscan2
- KIF21B | c.4298A>T p.N1433I (on ENST00000422435 / NM_001252100.2; = p.N1420I on NM_017596.4) | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59760863; called by muse, mutect2
- KIT | c.2597G>C p.G866A | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55391351, COSV55408604; called by muse, mutect2, varscan2
- KLK15 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); catalogued as COSV56827495; called by muse, mutect2, varscan2
- KREMEN1 | c.1114C>G p.P372A (on ENST00000407188; = p.P374A on NM_032045.5) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100588812, COSV59913524; called by mutect2, varscan2
- KRT3 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.332); catalogued as rs1389289222, COSV100527108, COSV58816182, COSV58817076; called by muse, mutect2, varscan2
- LAG3 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV52568106; called by muse, mutect2, varscan2
- LARGE1 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.089); catalogued as rs778360056, COSV61665342; ClinVar: uncertain significance; called by mutect2, varscan2
- LARGE1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.034); catalogued as rs1427588155, COSV61665348; called by muse, mutect2, varscan2
- LDB2 | c.907G>T p.G303* | Nonsense Mutation (SNP) | VAF 14/99 reads (14%) | catalogued as COSV58773698; called by muse, varscan2
- LGR5 | c.19G>C p.G7R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as rs765147377, COSV57006814; called by muse, mutect2, varscan2
- LRFN2 | c.1166C>G p.T389S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as COSV57830001; called by mutect2, varscan2
- LRP1B | c.9151G>T p.D3051Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67243134; called by muse, mutect2, varscan2
- LRP1B | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67187579, COSV67243146; called by muse, mutect2, varscan2
- LRP2 | c.289T>A p.S97T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.438); catalogued as rs1468975390, COSV55560647; called by muse, mutect2, varscan2
- LRRC66 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV58634935; called by muse, mutect2, varscan2
- LRRK1 | c.4672G>A p.E1558K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.165); catalogued as COSV52617563; called by muse, mutect2, varscan2
- MAGEB4 | c.812T>C p.L271P | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66776006; called by muse, mutect2, varscan2
- MAGEC2 | c.193G>C p.G65R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); catalogued as COSV56000260, COSV99909515; called by muse, mutect2, varscan2
- MAN1A1 | c.1280A>T p.D427V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV63788095; called by muse, mutect2, varscan2
- MAP3K1 | c.4367A>G p.N1456S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs1380085243, COSV68124939; called by muse, mutect2, varscan2
- MAPK8 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs202013888, COSV64409929, COSV64411041; called by muse, mutect2, varscan2
- MAPK8 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV64409943, COSV64410515, COSV64410559; called by muse, mutect2, varscan2
- MBD5 | c.2482A>T p.I828F | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.629); catalogued as COSV68698135; called by mutect2, varscan2
- MCCC1 | c.1334A>G p.Q445R | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.158); catalogued as rs747169908, COSV55608123; called by muse, mutect2, varscan2
- MCRS1 | c.1367C>A p.A456D | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV57791567; called by muse, mutect2, varscan2
- MDGA2 | c.1438G>T p.D480Y (on ENST00000399232 / NM_001113498.2; = p.D182Y on NM_182830.4) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62100488, COSV62111113; called by muse, mutect2, varscan2
- METAP1 | c.417G>A p.M139I | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.112); catalogued as COSV56444740; called by muse, mutect2, varscan2
- MGAM | c.799G>T p.G267* | Nonsense Mutation (SNP) | VAF 73/159 reads (46%) | catalogued as COSV71885112, COSV71885680; called by muse, mutect2, varscan2
- MGAT3 | c.714C>A p.C238* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100361826, COSV57866511; called by muse, mutect2, varscan2
- MINDY4 | c.1870G>T p.E624* | Nonsense Mutation (SNP) | VAF 57/153 reads (37%) | catalogued as COSV54675683; called by muse, varscan2
- MMP2 | c.1498C>A p.R500S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.364); catalogued as COSV54602924; called by muse, mutect2, varscan2
- MOK | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV51966051; called by muse, mutect2, varscan2
- MS4A6E | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV55727447; called by muse, varscan2
- MS4A6E | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 28/91 reads (31%) | catalogued as COSV55726728, COSV55728023; called by muse, varscan2
- MS4A7 | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV55730630; called by muse, mutect2, varscan2
- MTMR11 | c.1891C>A p.Q631K (on ENST00000439741 / NM_001145862.2; = p.Q559K on NM_181873.3) | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.82); catalogued as COSV99641497; called by muse, mutect2, varscan2
- MTNR1B | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57067290; called by muse, mutect2
- MTOR | c.6067T>G p.W2023G | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63874032; called by muse, mutect2
- MUC16 | c.16310A>C p.Q5437P | Missense Mutation (SNP) | VAF 17/252 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as COSV67476963; called by muse, mutect2
- MYF5 | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57354545, COSV57355606; called by muse, mutect2, varscan2
- MYH2 | c.3581C>A p.T1194K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV55441765; called by muse, mutect2, varscan2
- MYH4 | c.1753T>G p.Y585D | Missense Mutation (SNP) | VAF 56/81 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55121193; called by muse, mutect2, varscan2
- MYOCD | c.2236G>T p.E746* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100591337, COSV58506726; called by muse, mutect2, varscan2
- NAV3 | c.3047C>A p.T1016N | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57074258, COSV57092060; called by muse, mutect2, varscan2
- NDST1 | c.1091A>C p.H364P | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV55788519; called by muse, mutect2, varscan2
- NEB | c.16613C>A p.A5538D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51430932; called by muse, mutect2, varscan2
- NEBL | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65804195; called by muse, mutect2, varscan2
- NEUROD4 | c.816C>A p.D272E | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV54472477; called by muse, mutect2, varscan2
- NHLRC1 | c.899G>C p.S300T | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV61481653; called by muse, mutect2, varscan2
- NID2 | c.1265C>A p.P422H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53498983; called by muse, mutect2, varscan2
- NIN | c.3780C>A p.D1260E | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV55396529; called by muse, mutect2, varscan2
- NIPA1 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100507723, COSV61680220; called by muse, mutect2, varscan2
- NLRP12 | c.462C>A p.S154R | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV60749991; called by muse, mutect2, varscan2
- NOS2 | c.3425C>T p.A1142V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs200748226; called by muse, mutect2, varscan2
- NOX4 | c.1700G>T p.G567V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV54457161; called by muse, mutect2, varscan2
- NRAP | c.5091G>C p.R1697= (on ENST00000359988 / NM_001322945.2; = p.R1662= on NM_006175.4) | Splice Region (SNP) | VAF 18/42 reads (43%) | catalogued as COSV63491536, COSV63492054; called by muse, mutect2, varscan2
- NRG2 | c.707G>C p.R236P | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV56835774; called by muse, mutect2, varscan2
- NUP37 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51838415; called by muse, mutect2, varscan2
- NYAP1 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55719928; called by muse, mutect2, varscan2
- OR10G7 | c.626G>T p.C209F | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57867780; called by muse, mutect2, varscan2
- OR10P1 | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59007656; called by muse, mutect2, varscan2
- OR13G1 | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62944611; called by muse, mutect2, varscan2
- OR14J1 | c.854C>A p.P285Q | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65845790; called by muse, varscan2
- OR1G1 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV61030369; called by muse, mutect2, varscan2
- OR2C3 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV63575483; called by muse, mutect2, varscan2
- OR2T3 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs758796972, COSV62082828; called by muse, mutect2, varscan2
- OR2T4 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.086); catalogued as COSV63544449; called by muse, mutect2, varscan2
- OR2T4 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.246); catalogued as rs1406905409, COSV63544452; called by muse, mutect2, varscan2
- OR51L1 | c.786G>C p.M262I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV58623788, COSV58625139; called by mutect2, varscan2
- OR5B12 | c.782A>T p.N261I | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV56905676; called by muse, mutect2, varscan2
- OR5D13 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.05); catalogued as COSV62334336, COSV62335498; called by muse, mutect2, varscan2
- OR5T1 | c.697A>T p.I233F | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57303520; called by muse, mutect2, varscan2
- OR6A2 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV60265293; called by muse, mutect2, varscan2
- OR8A1 | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52509045, COSV52509116; called by muse, mutect2
- OR9I1 | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs758496662, COSV56926858; called by muse, mutect2, varscan2
- PABPC3 | c.1265T>C p.I422T | Missense Mutation (SNP) | VAF 49/157 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55802548; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2335C>G p.P779A (on ENST00000259318 / NM_001136562.3; = p.P1010A on NM_007203.5) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV52178510; called by mutect2, varscan2
- PANK2 | c.981+1G>A p.X327_splice (on ENST00000316562 / NM_153638.3; = p.X36_splice on NM_024960.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV57255255; called by muse, mutect2, varscan2
- PANX3 | c.140T>C p.L47S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52512836; called by muse, mutect2, varscan2
- PAPPA2 | c.1748T>A p.L583H | Missense Mutation (SNP) | VAF 80/138 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62781102; called by muse, mutect2, varscan2
- PAX6 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as rs1159095794, COSV53794393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCCB | c.800C>G p.A267G | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.433); catalogued as rs774249198, COSV52446239; called by muse, mutect2, varscan2
- PCDH11X | c.3704C>A p.P1235Q | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV53451628; called by muse, mutect2, varscan2
- PCDH8 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV58813687; called by muse, mutect2, varscan2
- PCDHA13 | c.1970C>A p.P657H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56520036, COSV56541576; called by mutect2, varscan2
- PCDHA3 | c.97T>A p.Y33N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65368470; called by muse, mutect2, varscan2
- PCDHA4 | c.1903C>G p.R635G | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.722); catalogued as rs746844684, COSV63542556, COSV63543284; called by muse, mutect2, varscan2
- PCDHB9 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.019); catalogued as COSV53380984; called by mutect2, varscan2
- PCM1 | c.2678C>G p.S893C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61517601; called by muse, mutect2, varscan2
- PHF2 | c.1084C>G p.Q362E | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV63681989; called by muse, mutect2, varscan2
- PHF20L1 | c.2770G>A p.V924I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs774111326, COSV55194894; called by muse, mutect2, varscan2
- PIGZ | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV99434012; called by muse, mutect2, varscan2
- PITPNC1 | c.922G>T p.D308Y | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs776740461, COSV55452901; called by muse, mutect2, varscan2
- PKD1 | c.7588G>T p.G2530C | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51919778; called by mutect2, varscan2
- PKHD1 | c.3014C>A p.A1005D | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1167032889, COSV61883846; called by muse, mutect2, varscan2
- PLCL1 | c.973A>T p.K325* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV101407202, COSV70843687; called by muse, mutect2, varscan2
- PLEKHF1 | c.39G>C p.Q13H | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV71410207; called by muse, mutect2, varscan2
- PLXND1 | c.3574G>T p.G1192W | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs748452504, COSV100140572, COSV60709375; called by muse, mutect2, varscan2
- PPP2R2C | c.597G>T p.W199C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58673840; called by muse, mutect2, varscan2
- PRDM16 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV54597163; called by muse, mutect2, varscan2
- PROX2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV71520096; called by muse, mutect2, varscan2
- PRPF4B | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.063); catalogued as rs1180223836, COSV61784690; called by muse, mutect2, varscan2
- PRRC2C | c.2762C>T p.P921L (on ENST00000367742; = p.P919L on NM_015172.4) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV58907982; called by muse, mutect2, varscan2
- PRUNE2 | c.4763C>G p.T1588S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as COSV65043455; called by muse, mutect2, varscan2
- PTCD3 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769376151, COSV54481244; called by muse, mutect2, varscan2
- PYGO2 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV100869002; called by muse, mutect2, varscan2
- RALA | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV50049641; called by muse, mutect2, varscan2
- RASGRP4 | c.346C>A p.L116M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.259); catalogued as COSV53096423; called by muse, mutect2, varscan2
- RC3H2 | c.3172G>T p.E1058* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV61801268; called by muse, mutect2, varscan2
- REG3A | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59410325; called by muse, mutect2
- RGS12 | c.1389G>T p.R463S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV60907081; called by mutect2, varscan2
- RNFT2 | c.1330T>C p.Y444H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57486912; called by muse, mutect2, varscan2
- RPAP3 | c.497A>C p.N166T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50042189; called by muse, mutect2, varscan2
- RPS6KA2 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV55816087, COSV55822982; called by muse, mutect2, varscan2
- RSPH6A | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as rs1191340867, COSV55573418; called by muse, mutect2, varscan2
- SCN11A | c.2321G>A p.W774* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV100180939, COSV56573136; called by muse, mutect2, varscan2
- SCN1A | c.5629G>A p.G1877R (on ENST00000303395 / NM_001202435.3; = p.G1866R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57676252; called by muse, mutect2, varscan2
- SEZ6L2 | c.707G>C p.G236A (on ENST00000308713 / NM_001114099.3; = p.G166A on NM_012410.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV58098637, COSV58100989, COSV58104211; called by muse, mutect2, varscan2
- SH3BGRL | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs777161866, COSV64621752; called by mutect2, varscan2
- SH3TC2 | c.279+1G>T p.X93_splice | Splice Site (SNP) | VAF 19/56 reads (34%) | catalogued as COSV60464871; called by muse, mutect2, varscan2
- SHPRH | c.2224T>A p.S742T | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV51612801; called by muse, mutect2, varscan2
- SI | c.1635C>A p.C545* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV52286669; called by muse, varscan2
- SLC12A8 | c.1626C>G p.S542R | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV58867693; called by muse, mutect2, varscan2
- SLC13A1 | c.829C>A p.R277S | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV52013593, COSV52017130; called by muse, mutect2, varscan2
- SLC15A4 | c.696C>A p.C232* | Nonsense Mutation (SNP) | VAF 35/122 reads (29%) | catalogued as COSV57161857, COSV57163461; called by muse, mutect2, varscan2
- SLC17A8 | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV60124900, COSV60126637; called by mutect2, varscan2
- SLC22A9 | c.1312T>A p.L438M | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV54168246; called by muse, mutect2, varscan2
- SLC4A4 | c.1535G>A p.G512E (on ENST00000264485 / NM_001098484.3; = p.G468E on NM_003759.4) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV52628997; called by muse, mutect2, varscan2
- SLC6A13 | c.1807T>C p.*603Qext*75 | Nonstop Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs1372326421, COSV58258061; called by muse, mutect2, varscan2
- SLC6A15 | c.2020A>T p.T674S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV57025121; called by muse, mutect2, varscan2
- SLC9A9 | c.1774C>A p.Q592K | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as CM157838, COSV57229825, COSV57234111; called by muse, mutect2, varscan2
- SLCO1B3 | c.2057C>G p.T686R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV53940834, COSV99681073; called by muse, mutect2, varscan2
- SLITRK3 | c.2561G>C p.G854A | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53850036, COSV53852503; called by muse, mutect2, varscan2
- SLITRK3 | c.1871C>T p.P624L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV53846662, COSV53846854; called by muse, mutect2, varscan2
- SMG1 | c.6117G>T p.W2039C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV67172919; called by muse, mutect2, varscan2
- SNIP1 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs1290948112, COSV56167249; called by muse, mutect2
- SPAG16 | c.439G>C p.V147L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55987427; called by muse, mutect2, varscan2
- SRBD1 | c.2718C>A p.F906L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV55401198; called by mutect2, varscan2
- STIM2 | c.1153del p.E385Kfs*22 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as COSV52836933; called by mutect2, pindel
- SUPT7L | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 99/257 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1558497593, COSV53115693; called by muse, mutect2, varscan2
- SWT1 | c.374A>G p.H125R | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV62256715; called by muse, mutect2, varscan2
- SYNE1 | c.15839A>G p.Q5280R (on ENST00000367255 / NM_182961.4; = p.Q5209R on NM_033071.3) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs567339732, COSV55025264; called by mutect2, varscan2
- TAF3 | c.2592G>T p.Q864H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV60208208; called by muse, mutect2, varscan2
- TANGO6 | c.3103A>T p.T1035S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV55768178; called by muse, mutect2
- TAS2R19 | c.308G>T p.S103I | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66828644; called by muse, mutect2, varscan2
- TDRD5 | c.2482C>T p.Q828* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV54245813; called by muse, mutect2, varscan2
- TDRD6 | c.1115T>A p.V372E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs762656472, COSV60176674; called by muse, varscan2
- TEAD2 | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99678844; called by muse, mutect2, varscan2
- TEX15 | c.5726C>G p.S1909* (on ENST00000256246; = p.S2292* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV56348900; called by muse, mutect2, varscan2
- TGM7 | c.1221G>C p.W407C | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV71772918; called by mutect2, varscan2
- THEM4 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.038); catalogued as COSV64295495; called by muse, mutect2, varscan2
- THEMIS | c.1414G>T p.V472L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV64072168, COSV64072813; called by muse, mutect2
- THEMIS | c.333A>T p.R111S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV64072173; called by muse, mutect2, varscan2
- TM4SF19 | c.554T>A p.L185Q | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as COSV56556989; called by muse, mutect2, varscan2
- TMEM100 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70118095, COSV70118125; called by muse, mutect2, varscan2
- TMEM132D | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67159882; called by mutect2, varscan2
- TMEM132D | c.1189C>G p.Q397E | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV70611677; called by muse, mutect2, varscan2
- TMPRSS11D | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.548); catalogued as rs751096680, COSV52224324; called by muse, mutect2, varscan2
- TP53 | c.472del p.R158Afs*12 | Frame Shift Del (DEL) | VAF 13/31 reads (42%) | catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by mutect2, pindel, varscan2
- TRAF4 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.969); catalogued as COSV52046260; called by muse, mutect2, varscan2
- TRHDE | c.1550A>T p.D517V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53852028; called by muse, mutect2, varscan2
- TRIM23 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV51552638; called by muse, mutect2, varscan2
- TRIP11 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs771215521, COSV50934253; called by muse, mutect2, varscan2
- TRPM3 | c.4219T>C p.Y1407H (on ENST00000357533 / NM_001366142.2; = p.Y1262H on NM_020952.6) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); catalogued as COSV62589243; called by muse, mutect2, varscan2
- TRPM6 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.304); catalogued as COSV62515150; called by muse, varscan2
- TRPV5 | c.1536C>A p.F512L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54684851, COSV54687425; called by muse, mutect2
- TTN | c.79652A>G p.E26551G (on ENST00000591111; = p.E19127G on NM_003319.4) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | PolyPhen probably damaging (0.997); catalogued as COSV60167996; called by muse, mutect2, varscan2
- TTN | c.24662C>A p.S8221Y (on ENST00000591111; = p.S7294Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | PolyPhen possibly damaging (0.816); catalogued as COSV59912493, COSV60356860; called by mutect2, varscan2
- TTN | c.19588A>G p.T6530A (on ENST00000591111; = p.T5603A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/98 reads (9%) | PolyPhen benign (0); catalogued as COSV60168061; called by muse, mutect2
- TXLNB | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV64444661; called by muse, varscan2
- UBR5 | c.6887A>G p.Y2296C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55292235; called by muse, mutect2, varscan2
- UMPS | c.1372G>C p.D458H | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV51737904; called by muse, mutect2, varscan2
- UNC45B | c.1843A>T p.K615* | Nonsense Mutation (SNP) | VAF 31/137 reads (23%) | catalogued as COSV52097592; called by muse, mutect2, varscan2
- USH2A | c.13105G>T p.A4369S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.55); PolyPhen benign (0.179); catalogued as COSV56393389; called by muse, mutect2, varscan2
- USH2A | c.12540C>A p.N4180K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV56393402; called by muse, mutect2, varscan2
- USH2A | c.2957A>T p.K986I | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as COSV56393415; called by muse, mutect2, varscan2
- USP13 | c.1896del p.I633* | Frame Shift Del (DEL) | VAF 17/121 reads (14%) | catalogued as rs780272979; called by mutect2, pindel, varscan2
- USP34 | c.3133G>T p.G1045C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766155323, COSV68398612; called by muse, mutect2, varscan2
- USP54 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV60444475; called by muse, mutect2, varscan2
- USP7 | c.2416G>T p.D806Y | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61215743; called by muse, mutect2, varscan2
- USP9X | c.2393C>T p.T798M | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61071443; called by muse, mutect2, varscan2
- VEPH1 | c.277A>C p.N93H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV62880306; called by muse, mutect2, varscan2
- WDR36 | c.2653G>A p.D885N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV72605318; called by muse, mutect2, varscan2
- WDR64 | c.1291+2T>C p.X431_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as rs749509520, COSV63797438; called by muse, mutect2, varscan2
- WIPF2 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.881); catalogued as COSV60274433; called by muse, mutect2, varscan2
- WWP1 | c.896C>G p.T299S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV55360851; called by muse, mutect2, varscan2
- XIRP2 | c.97T>A p.C33S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV54712754; called by mutect2, varscan2
- ZBBX | c.1901C>A p.S634* | Nonsense Mutation (SNP) | VAF 36/200 reads (18%) | catalogued as COSV56793806; called by muse, mutect2, varscan2
- ZBTB38 | c.2739C>A p.D913E | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58542922; called by mutect2, varscan2
- ZBTB38 | c.3385C>T p.Q1129* | Nonsense Mutation (SNP) | VAF 16/215 reads (7%) | catalogued as COSV58542934; called by muse, mutect2
- ZDBF2 | c.6754A>T p.K2252* | Nonsense Mutation (SNP) | VAF 9/22 reads (41%) | catalogued as COSV65627670; called by muse, mutect2, varscan2
- ZEB1 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as COSV58048275; called by muse, mutect2, varscan2
- ZEB2 | c.1409C>A p.T470N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.992); catalogued as COSV57960305; called by muse, mutect2, varscan2
- ZFHX3 | c.10647G>T p.E3549D | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV51724477; called by muse, mutect2, varscan2
- ZFHX4 | c.6661G>C p.D2221H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51460666; called by muse, mutect2
- ZIM3 | c.722A>C p.H241P | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54144195; called by muse, mutect2, varscan2
- ZNF18 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.831); catalogued as rs1225834251, COSV59551705; called by muse, mutect2, varscan2
- ZNF391 | c.766A>T p.K256* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV55123348; called by muse, mutect2, varscan2
- ZNF420 | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.091); catalogued as COSV58494892; called by muse, mutect2, varscan2
- ZNF639 | c.1358A>G p.K453R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV58383640; called by muse, mutect2, varscan2
- ZNF667 | c.985C>A p.P329T | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV52636358, COSV99410409; called by muse, mutect2, varscan2
- ZNF670 | c.130+1G>T p.X44_splice | Splice Site (SNP) | VAF 14/53 reads (26%) | catalogued as COSV63608410; called by muse, mutect2, varscan2
- ZNF675 | c.1372G>T p.G458C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63096539; called by mutect2, varscan2
- ZNF682 | c.505A>G p.T169A | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs913906245, COSV62067722; called by muse, mutect2, varscan2
- ZNF695 | c.541del p.E181Kfs*17 | Frame Shift Del (DEL) | VAF 12/88 reads (14%) | catalogued as COSV60587867; called by mutect2, pindel, varscan2
- ZNF714 | c.1276A>T p.K426* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV52513373; called by muse, mutect2, varscan2
- ZSCAN4 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV59000592; called by muse, mutect2, varscan2
- ACTL7A | c.253_261del p.F85_G87del | In Frame Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel
- CITED2 | c.159_181del p.E54Qfs*33 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- FCGBP | c.748A>T p.T250S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- IGHG3 | c.383del p.C129Afs*54 | Frame Shift Del (DEL) | VAF 32/126 reads (25%) | called by pindel, varscan2
- IGKV1-17 | c.313T>G p.F105V | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV3D-11 | c.135del p.S46Vfs*8 | Frame Shift Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel, varscan2
- IGKV3D-20 | c.246G>C p.R82S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- INHA | c.50A>T p.H17L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- KCNJ15 | c.343_355del p.T115Sfs*37 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- MR1 | c.957_983del p.V320_R328del | In Frame Del (DEL) | VAF 8/93 reads (9%) | called by mutect2, pindel
- NTN5 | c.178dup p.T60Nfs*60 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- OR11H12 | c.725del p.G242Vfs*34 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- OR4A15 | c.793dup p.I265Nfs*2 | Frame Shift Ins (INS) | VAF 27/205 reads (13%) | called by mutect2, pindel, varscan2
- OR52R1 | c.945del p.P316Pfs*? | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel
- P4HA3 | c.519del p.K174Nfs*53 | Frame Shift Del (DEL) | VAF 70/180 reads (39%) | called by mutect2, pindel, varscan2
- PRAMEF5 | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- TRBV24-1 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.42); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- TTN | c.6233del p.P2078Qfs*61 (on ENST00000591111; = p.P2032Qfs*61 on NM_003319.4) | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- TXNDC16 | c.2398dup p.W800Lfs*3 | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- ZBTB16 | c.1488del p.K497Sfs*121 | Frame Shift Del (DEL) | VAF 23/48 reads (48%) | called by mutect2, pindel, varscan2
- ABHD13 | c.633A>C p.S211= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs199907641, COSV65534838, COSV65535177; called by muse, mutect2, varscan2
- ADAMTS16 | c.924T>C p.H308= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs532425132, COSV56995806; called by muse, mutect2, varscan2
- ADGRV1 | c.18219G>A p.V6073= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as COSV67989147; called by muse, mutect2, varscan2
- AHNAK2 | c.2730C>A p.A910= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as rs149453124, COSV100319296; called by mutect2, varscan2
- ASXL1 | c.2208A>T p.T736= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV60112444; called by muse, mutect2, varscan2
- BLK | c.153G>T p.P51= | Silent (SNP) | VAF 21/153 reads (14%) | catalogued as COSV52053620; called by muse, mutect2, varscan2
- BOD1L1 | c.5025A>G p.E1675= | Silent (SNP) | VAF 30/170 reads (18%) | catalogued as COSV50023331; called by muse, mutect2, varscan2
- C9orf72 | c.6G>A p.S2= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs138028443; called by muse, mutect2, varscan2
- CASS4 | c.1644G>A p.V548= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV64387206; called by mutect2, varscan2
- CCIN | c.738C>A p.T246= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV58725041, COSV58725066; called by muse, mutect2, varscan2
- CD200 | c.372G>T p.L124= (on ENST00000473539 / NM_001004196.3; = p.L99= on NM_005944.7 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100238405, COSV100238541; called by muse, mutect2, varscan2
- CLSTN1 | c.2580G>T p.A860= (on ENST00000377298 / NM_001009566.3; = p.A850= on NM_014944.4) | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV63129763; called by muse, mutect2, varscan2
- COL12A1 | c.7605T>A p.A2535= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV59399862; called by muse, mutect2, varscan2
- CPN2 | c.439C>T p.L147= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV60470937; called by muse, mutect2, varscan2
- CSMD3 | c.483T>C p.V161= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs1456552332, COSV52229860; called by muse, mutect2, varscan2
- CWC25 | c.1116G>T p.R372= | Silent (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- DCHS1 | c.1003C>A p.R335= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV55038412; called by muse, mutect2, varscan2
- DHX38 | c.2748G>T p.P916= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV51699070; called by muse, mutect2, varscan2
- DNAH11 | c.2328G>T p.T776= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs372387032, COSV60964871; called by muse, mutect2, varscan2
- DNAH7 | c.11754T>A p.P3918= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV56772617; called by muse, mutect2, varscan2
- EPHA7 | c.1860T>A p.A620= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV65186386; called by muse, mutect2, varscan2
- EPHB6 | c.885A>T p.V295= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV67419368; called by muse, mutect2, varscan2
- FAM135B | c.1116C>T p.H372= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV52736425; called by muse, mutect2, varscan2
- FAM160A2 | c.1917A>T p.P639= (on ENST00000449352 / NM_001098794.2; = p.P653= on NM_032127.4) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV56412654; called by muse, mutect2, varscan2
- FAT4 | c.7770C>T p.T2590= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV58694250; called by muse, mutect2
- FCGBP | c.9273C>T p.T3091= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as rs1442363435; called by muse, varscan2
- FCGR2B | c.378G>A p.L126= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99375466; called by mutect2, varscan2
- FLG2 | c.1797C>A p.G599= | Silent (SNP) | VAF 86/225 reads (38%) | catalogued as COSV66170166; called by muse, mutect2, varscan2
- FRK | c.726T>A p.S242= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV73384084; called by muse, mutect2, varscan2
- GDF2 | c.927T>A p.A309= | Silent (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- GLI2 | c.342C>T p.P114= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs1443099787, COSV58045535; called by muse, mutect2, varscan2
- H3C6 | c.54C>A p.R18= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV64519685; called by muse, mutect2, varscan2
- HTR1E | c.987G>T p.L329= | Silent (SNP) | VAF 26/135 reads (19%) | catalogued as COSV59508927; called by muse, varscan2
- IFT122 | c.2427G>T p.L809= (on ENST00000348417 / NM_052989.3; = p.L750= on NM_018262.4) | Silent (SNP) | VAF 11/142 reads (8%) | catalogued as COSV56204934; called by muse, mutect2
- IGHV1-45 | c.210C>A p.I70= | Silent (SNP) | VAF 30/102 reads (29%) | called by muse, mutect2, varscan2
- IGHV2-5 | c.273C>T p.T91= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs569991253; called by muse, mutect2, varscan2
- ITGAL | c.2724G>T p.L908= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV63323032; called by muse, mutect2, varscan2
- KCNK5 | c.573C>A p.I191= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV63989102; called by muse, mutect2, varscan2
- KLK5 | c.519C>T p.N173= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs201276529, COSV60450787; called by muse, mutect2, varscan2
- KMT2C | c.12063G>T p.L4021= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV51460024; called by muse, mutect2, varscan2
- KRT33B | c.909C>T p.S303= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs770330752, COSV52441438, COSV52442296; called by mutect2, varscan2
- LAMA2 | c.6057T>G p.T2019= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV70351073; called by muse, mutect2, varscan2
- LCTL | c.150C>T p.Y50= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV58422432; called by muse, mutect2
- LRP1B | c.8527C>A p.R2843= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV67243141, COSV99081258; called by muse, mutect2, varscan2
- LRRC15 | c.1170C>G p.G390= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV61650631; called by muse, mutect2, varscan2
- LRRTM1 | c.891C>G p.P297= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV54443800; called by muse, mutect2, varscan2
- MAP4K1 | c.841C>A p.R281= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs745506984, COSV67711110, COSV67711312; called by muse, mutect2, varscan2
- MOGAT2 | c.891G>A p.S297= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs369041843, COSV52220434; called by muse, mutect2, varscan2
- MROH1 | c.1254C>T p.A418= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV58190953; called by muse, mutect2
- NBAS | c.6072G>T p.V2024= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV55727923; called by mutect2, varscan2
- NEK11 | c.594T>C p.Y198= | Silent (SNP) | VAF 57/122 reads (47%) | catalogued as COSV63582018; called by muse, mutect2, varscan2
- OR10T2 | c.69G>A p.E23= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV57782146; called by muse, mutect2, varscan2
- OR2M2 | c.264C>A p.G88= | Silent (SNP) | VAF 29/243 reads (12%) | catalogued as COSV62898747; called by muse, mutect2, varscan2
- OR2M3 | c.96G>C p.L32= | Silent (SNP) | VAF 28/174 reads (16%) | catalogued as COSV71759141; called by muse, mutect2, varscan2
- OR5F1 | c.462G>A p.L154= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1411799201, COSV53546439; called by muse, mutect2, varscan2
- OR5W2 | c.279C>A p.P93= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV100747780; called by muse, mutect2, varscan2
- PANK1 | c.54G>C p.A18= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs1299617540, COSV56809019; called by muse, varscan2
- PCDHA2 | c.1725C>A p.G575= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as rs782143025, COSV65367026, COSV65368460; called by muse, mutect2, varscan2
- PEG3 | c.3627G>T p.R1209= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV55638527, COSV99688727; called by muse, mutect2, varscan2
- PIGR | c.1605C>A p.T535= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV62904455; called by muse, varscan2
- PKHD1 | c.3015C>G p.A1005= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV61871765, COSV61883821; called by muse, mutect2, varscan2
- PLA2G4A | c.1830T>C p.Y610= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs1049559531, COSV66555010; called by muse, mutect2, varscan2
- PLXNA4 | c.5490C>T p.N1830= | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs201396021; called by muse, mutect2, varscan2
- PSG7 | c.1026C>T p.T342= | Silent (SNP) | VAF 44/207 reads (21%) | catalogued as COSV68445546; called by muse, mutect2, varscan2
- RUBCN | c.1905G>A p.K635= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs752331965, COSV56369040; called by muse, mutect2, varscan2
- S100A11 | c.84T>C p.D28= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as COSV54975903; called by muse, mutect2, varscan2
- SLC22A2 | c.567A>T p.A189= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV65266926; called by muse, mutect2, varscan2
- SLC27A6 | c.597C>A p.T199= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV52484733; called by muse, mutect2, varscan2
- SLC39A10 | c.2397G>T p.G799= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV56772605; called by muse, mutect2, varscan2
- SLC5A7 | c.189C>T p.V63= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV50894663; called by muse, mutect2, varscan2
- SLIT2 | c.4485G>T p.L1495= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV56580021; called by muse, mutect2, varscan2
- SUGCT | c.1230C>T p.H410= (on ENST00000335693 / NM_001193313.2; = p.H436= on NM_024728.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs368801829; called by muse, mutect2, varscan2
- TBC1D32 | c.1914T>C p.S638= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV51546866; called by muse, mutect2, varscan2
- TBC1D8 | c.1605G>T p.L535= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2
- TNC | c.4710G>C p.L1570= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV60786767; called by muse, mutect2, varscan2
- UBQLNL | c.498G>T p.V166= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs553557959, COSV66493871; called by muse, mutect2, varscan2
- UMODL1 | c.900G>T p.T300= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV68555057, COSV68556815; called by muse, mutect2, varscan2
- UPF2 | c.2583A>G p.Q861= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV62661779; called by muse, mutect2, varscan2
- ZNF23 | c.519A>G p.L173= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as COSV61841225; called by muse, mutect2, varscan2
- ZNF613 | c.1497C>T p.L499= (on ENST00000293471 / NM_001031721.4; = p.L463= on NM_024840.4) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV53271212, COSV53272685; called by muse, mutect2, varscan2
- ZNF677 | c.663C>A p.I221= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV61720705; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1217G>T | Intron (SNP) | VAF 16/40 reads (40%) | catalogued as rs377373434, COSV56100072; called by muse, mutect2, varscan2
- AC132217.2 | c.*46+1216G>T | Intron (SNP) | VAF 16/39 reads (41%) | catalogued as COSV56099830, COSV56100079; called by muse, mutect2, varscan2
- ADA2 | c.753+3993C>G | Intron (SNP) | VAF 9/38 reads (24%) | catalogued as rs772934083, COSV99376565; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827138 T>C | 3'Flank (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- COL4A1 | c.615+144C>A | Intron (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- DST | c.16635+238A>G | Intron (SNP) | VAF 10/33 reads (30%) | catalogued as COSV55024253; called by muse, mutect2, varscan2
- ENPP2 | c.973-1989A>G | Intron (SNP) | VAF 9/120 reads (8%) | catalogued as COSV99309609; called by muse, mutect2
- FAM107B | c.-1C>T | 5'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99474641; called by mutect2, varscan2
- FBXL21P | n.1207C>T | RNA (SNP) | VAF 21/56 reads (38%) | catalogued as COSV51809508; called by muse, mutect2, varscan2
- H3-3B | chr17:75784728 C>G | 5'Flank (SNP) | VAF 14/31 reads (45%) | catalogued as COSV53143945, COSV99505490; called by muse, mutect2, varscan2
- KANSL2 | c.1348-328G>A | Intron (SNP) | VAF 9/42 reads (21%) | catalogued as COSV67611101; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397780 G>A | 3'Flank (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- OR52A4P | n.898T>C | RNA (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- PRUNE2 | c.756+35228G>C | Intron (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100943386; called by muse, mutect2, varscan2
- RAB3GAP2 | c.811+1738del | Intron (DEL) | VAF 12/52 reads (23%) | called by pindel, varscan2*
- SSPOP | n.1783C>T | RNA (SNP) | VAF 17/25 reads (68%) | catalogued as COSV50488165; called by muse, mutect2, varscan2
- TCP10L3 | n.601G>T | RNA (SNP) | VAF 19/100 reads (19%) | catalogued as COSV64751684; called by muse, mutect2, varscan2
- TTN | c.10360+1831C>A | Intron (SNP) | VAF 11/66 reads (17%) | catalogued as COSV60168075; called by muse, mutect2, varscan2
- Vault | n.71T>A | RNA (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- XIRP2 | c.*892C>A | 3'UTR (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99748903; called by muse, mutect2, varscan2
